Somatic mutation profile of tumor specimen MMRF_1269_1_BM_CD138pos (aliquot MMRF_1269_1_BM_CD138pos_T2_TSE61_L00080) from MMRF case MMRF_1269, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Dead; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 52.5 years (19,163 days).
Specimen MMRF_1269_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8c5a05aa-5a62-4f23-9199-48497dda2fde.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1269_1_PB_Whole (Blood Derived Normal), aliquot MMRF_1269_1_PB_Whole_C1_TSE61_L00081; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/448764e3-a5cc-4c59-9403-413cb6203614

The open-access MAF lists 98 somatic variants for this specimen: 50 protein-altering or splice-affecting, 10 silent, 38 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 46, 3'UTR 26, Silent 10, 5'UTR 6, Intron 3, 3'Flank 2, Frame Shift Ins 2, RNA 1, Nonsense Mutation 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.183A>T p.Q61H | Missense Mutation (SNP) | VAF 124/131 reads (95%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.316); catalogued as rs121913255, COSV54736320, COSV54736991, COSV54744813; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ADCY7 | c.1180G>A p.V394M | Missense Mutation (SNP) | VAF 127/264 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs763219848; called by muse, mutect2, varscan2
- ADGRD1 | c.458C>T p.S153F | Missense Mutation (SNP) | VAF 8/71 reads (11%) | SIFT tolerated (0.2); PolyPhen benign (0.005); catalogued as COSV55443627; called by muse, mutect2
- ASTN1 | c.1702G>C p.D568H | Missense Mutation (SNP) | VAF 36/132 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56079393; called by muse, mutect2, varscan2
- ASTN2 | c.2063T>G p.M688R (on ENST00000313400 / NM_001365069.1; = p.M637R on NM_014010.5) | Missense Mutation (SNP) | VAF 56/119 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as rs771348581; called by muse, mutect2, varscan2
- BNC2 | c.2071T>A p.F691I | Missense Mutation (SNP) | VAF 30/105 reads (29%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as COSV66155230; called by muse, mutect2, varscan2
- GLI2 | c.3568C>T p.P1190S (on ENST00000361492 / NM_001374353.1; = p.P1207S on NM_005270.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 7/90 reads (8%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0.142); catalogued as rs1400303256, COSV58048149; called by muse, mutect2
- GPC6 | c.640G>A p.A214T | Missense Mutation (SNP) | VAF 51/123 reads (41%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.694); catalogued as rs756656699, COSV65524625; called by muse, mutect2, varscan2
- KCNA5 | c.149C>T p.A50V | Missense Mutation (SNP) | VAF 44/88 reads (50%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.003); catalogued as COSV99363506; called by muse, mutect2, varscan2
- KDM6A | c.2066C>A p.S689* | Nonsense Mutation (SNP) | VAF 67/72 reads (93%) | catalogued as COSV100938704, COSV65045588; called by muse, mutect2, varscan2
- LRRC8C | c.200C>T p.S67F | Missense Mutation (SNP) | VAF 56/60 reads (93%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as rs1407694883; called by muse, mutect2, varscan2
- OR4K2 | c.272C>A p.T91N | Missense Mutation (SNP) | VAF 16/302 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.019); catalogued as COSV53848844; called by muse, mutect2
- PAX9 | c.644C>T p.S215F | Missense Mutation (SNP) | VAF 34/126 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.07); catalogued as rs1206808645; called by muse, mutect2, varscan2
- RSRC2 | c.1251A>C p.Q417H | Missense Mutation (SNP) | VAF 82/185 reads (44%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.977); catalogued as COSV59203858; called by muse, mutect2, varscan2
- TLE6 | c.868C>T p.L290F (on ENST00000246112 / NM_001143986.2; = p.L167F on NM_024760.3) | Missense Mutation (SNP) | VAF 80/318 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.617); catalogued as COSV55737741; called by muse, mutect2, varscan2
- ZFHX4 | c.8780C>T p.P2927L | Missense Mutation (SNP) | VAF 119/207 reads (57%) | SIFT tolerated (0.1); PolyPhen benign (0.08); catalogued as rs371706545, COSV50672287, COSV50678044; called by muse, mutect2, varscan2
- ZNF835 | c.850G>A p.A284T | Missense Mutation (SNP) | VAF 191/407 reads (47%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.773); catalogued as rs575232626, COSV101606360; called by muse, mutect2, varscan2
- ADAMTS5 | c.167A>T p.E56V | Missense Mutation (SNP) | VAF 13/168 reads (8%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.026); called by muse, mutect2
- ADCY2 | c.2389G>T p.G797C | Missense Mutation (SNP) | VAF 27/66 reads (41%) | SIFT tolerated (0.07); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- AGBL1 | c.1578C>A p.D526E | Missense Mutation (SNP) | VAF 17/25 reads (68%) | SIFT tolerated (0.62); PolyPhen benign (0.381); called by muse, mutect2, varscan2
- BUD13 | c.1183dup p.R395Kfs*9 | Frame Shift Ins (INS) | VAF 63/141 reads (45%) | called by mutect2, pindel, varscan2
- CACNA2D3 | c.1396A>C p.K466Q | Missense Mutation (SNP) | VAF 18/122 reads (15%) | SIFT tolerated (0.27); PolyPhen benign (0); called by muse, mutect2, varscan2
- CAMK1G | c.599T>C p.V200A | Missense Mutation (SNP) | VAF 16/128 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- CBLB | c.2774C>G p.P925R | Missense Mutation (SNP) | VAF 26/107 reads (24%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.235); called by muse, mutect2, varscan2
- CRYZL1 | c.484A>T p.I162F | Missense Mutation (SNP) | VAF 30/65 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); called by muse, mutect2, varscan2
- CYP7A1 | c.55T>A p.W19R | Missense Mutation (SNP) | VAF 32/56 reads (57%) | SIFT deleterious (0); PolyPhen possibly damaging (0.472); called by muse, mutect2, varscan2
- FAM135B | c.3991A>T p.T1331S | Missense Mutation (SNP) | VAF 31/124 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.388); called by muse, mutect2, varscan2
- FAM13C | c.94G>C p.D32H | Missense Mutation (SNP) | VAF 30/148 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.621); called by muse, mutect2, varscan2
- FBXW7 | c.97A>G p.M33V | Missense Mutation (SNP) | VAF 38/168 reads (23%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- FOXO4 | c.1067G>C p.G356A | Missense Mutation (SNP) | VAF 132/137 reads (96%) | SIFT tolerated (0.69); PolyPhen benign (0.219); called by muse, mutect2, varscan2
- GABRA4 | c.56C>G p.A19G | Missense Mutation (SNP) | VAF 15/49 reads (31%) | SIFT tolerated (0.17); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- HUWE1 | c.11333T>A p.M3778K | Missense Mutation (SNP) | VAF 25/46 reads (54%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.599); called by muse, mutect2, varscan2
- ITGA1 | c.1410G>T p.M470I | Missense Mutation (SNP) | VAF 29/84 reads (35%) | SIFT tolerated (0.32); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ITIH6 | c.1271T>A p.L424H | Missense Mutation (SNP) | VAF 8/188 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- KIF22 | c.1675A>C p.K559Q | Missense Mutation (SNP) | VAF 30/81 reads (37%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- LRP1B | c.9730T>C p.S3244P | Missense Mutation (SNP) | VAF 7/146 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.462); called by muse, mutect2
- LUZP2 | c.65A>G p.Q22R | Missense Mutation (SNP) | VAF 19/53 reads (36%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.957); called by muse, mutect2, varscan2
- MAGEC1 | c.863del p.P288Lfs*20 | Frame Shift Del (DEL) | VAF 30/192 reads (16%) | called by pindel, varscan2
- MINK1 | c.1863_1864dup p.A622Vfs*185 | Frame Shift Ins (INS) | VAF 72/176 reads (41%) | called by mutect2, pindel, varscan2
- MMP13 | c.304G>A p.G102S | Missense Mutation (SNP) | VAF 18/112 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.109); called by muse, mutect2, varscan2
- NYNRIN | c.694C>G p.P232A | Missense Mutation (SNP) | VAF 32/147 reads (22%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0); called by muse, mutect2, varscan2
- PPP2R1A | c.214C>G p.Q72E | Missense Mutation (SNP) | VAF 14/326 reads (4%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2
- RNF40 | c.1322T>A p.L441Q | Missense Mutation (SNP) | VAF 10/124 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- SIRT1 | c.1872G>T p.W624C | Missense Mutation (SNP) | VAF 3/44 reads (7%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.948); called by muse, mutect2
- SLC35G3 | c.479G>A p.C160Y | Missense Mutation (SNP) | VAF 409/882 reads (46%) | SIFT tolerated (0.47); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SLCO1C1 | c.1097T>C p.F366S | Missense Mutation (SNP) | VAF 44/151 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.444); called by muse, mutect2, varscan2
- TM7SF3 | c.988T>A p.F330I | Missense Mutation (SNP) | VAF 45/87 reads (52%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.867); called by muse, mutect2, varscan2
- TXNDC5 | c.724A>T p.I242F | Missense Mutation (SNP) | VAF 3/45 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- VAT1L | c.900G>T p.K300N | Missense Mutation (SNP) | VAF 38/89 reads (43%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZNF222 | c.638G>C p.R213T | Missense Mutation (SNP) | VAF 46/98 reads (47%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.891); called by muse, mutect2, varscan2
- ATP1A3 | c.2712T>C p.S904= (on ENST00000545399 / NM_001256214.2; = p.S891= on NM_152296.5) | Silent (SNP) | VAF 30/62 reads (48%) | catalogued as COSV57485134; called by muse, mutect2, varscan2
- CAD | c.4299C>A p.T1433= | Silent (SNP) | VAF 3/41 reads (7%) | called by muse, mutect2
- FFAR1 | c.279C>T p.G93= | Silent (SNP) | VAF 72/142 reads (51%) | catalogued as COSV99323420; called by muse, mutect2, varscan2
- GIPC3 | c.2487C>G p.S829= | Silent (SNP) | VAF 25/94 reads (27%) | called by muse, mutect2, varscan2
- MRC2 | c.2340C>T p.D780= | Silent (SNP) | VAF 95/220 reads (43%) | called by muse, mutect2, varscan2
- NCAM2 | c.2490A>C p.S830= | Silent (SNP) | VAF 43/112 reads (38%) | called by muse, mutect2, varscan2
- NFASC | c.3054G>A p.V1018= | Silent (SNP) | VAF 88/136 reads (65%) | catalogued as rs1417701276; called by muse, mutect2, varscan2
- PCDHGA3 | c.2106C>T p.C702= | Silent (SNP) | VAF 229/500 reads (46%) | catalogued as COSV53905493; called by muse, mutect2, varscan2
- PXDN | c.3195C>T p.F1065= | Silent (SNP) | VAF 23/128 reads (18%) | catalogued as rs751261227, COSV99414623; called by muse, mutect2, varscan2
- TAPBPL | c.717C>T p.Y239= | Silent (SNP) | VAF 128/262 reads (49%) | called by muse, mutect2, varscan2
- ADGRD1 | c.-394T>A | 5'UTR (SNP) | VAF 13/157 reads (8%) | called by muse, mutect2
- ALDH1A1 | c.*468A>C | 3'UTR (SNP) | VAF 13/114 reads (11%) | called by muse, mutect2, varscan2
- ASIC1 | c.*1893dup | 3'UTR (INS) | VAF 26/62 reads (42%) | called by mutect2, pindel, varscan2
- BEST3 | c.-62A>T | 5'UTR (SNP) | VAF 23/50 reads (46%) | called by muse, mutect2, varscan2
- CCBE1 | c.*1249A>G | 3'UTR (SNP) | VAF 33/78 reads (42%) | called by muse, mutect2, varscan2
- CCDC113 | c.*2616C>T | 3'UTR (SNP) | VAF 6/12 reads (50%) | called by muse, mutect2, varscan2
- CRK | c.*301C>A | 3'UTR (SNP) | VAF 20/122 reads (16%) | called by muse, mutect2, varscan2
- DSC3 | c.*2844T>A | 3'UTR (SNP) | VAF 16/31 reads (52%) | called by muse, mutect2, varscan2
- GLI3 | c.*1478C>T | 3'UTR (SNP) | VAF 56/119 reads (47%) | called by muse, mutect2, varscan2
- GULP1 | c.*1260G>C | 3'UTR (SNP) | VAF 6/88 reads (7%) | called by muse, mutect2
- HDDC3 | c.*310T>C | 3'UTR (SNP) | VAF 39/73 reads (53%) | called by muse, mutect2, varscan2
- MAPK1IP1L | c.*1335A>C | 3'UTR (SNP) | VAF 37/87 reads (43%) | called by muse, mutect2, varscan2
- MMAA | chr4:145657207 T>G | 3'Flank (SNP) | VAF 33/60 reads (55%) | called by muse, mutect2, varscan2
- OSBPL3 | c.*2732A>G | 3'UTR (SNP) | VAF 40/101 reads (40%) | called by muse, mutect2, varscan2
- PARP9 | c.2185+769C>T | Intron (SNP) | VAF 16/136 reads (12%) | called by muse, mutect2, varscan2
- PCDH10 | c.*102T>G | 3'UTR (SNP) | VAF 52/139 reads (37%) | called by muse, mutect2, varscan2
- PI15 | c.*4453C>G | 3'UTR (SNP) | VAF 8/238 reads (3%) | called by muse, mutect2
- PYY2 | n.183C>A | RNA (SNP) | VAF 50/97 reads (52%) | called by muse, mutect2, varscan2
- RBM33 | c.*1338A>T | 3'UTR (SNP) | VAF 35/153 reads (23%) | called by muse, mutect2, varscan2
- RERE | c.*1324T>C | 3'UTR (SNP) | VAF 6/148 reads (4%) | called by muse, mutect2
- RN7SL545P | chr15:22427639 T>A | 3'Flank (SNP) | VAF 194/485 reads (40%) | called by muse, mutect2, varscan2
- RPP38 | c.*81A>G | 3'UTR (SNP) | VAF 4/75 reads (5%) | called by muse, mutect2
- RSRC2 | c.*152T>G | 3'UTR (SNP) | VAF 77/148 reads (52%) | called by muse, mutect2, varscan2
- SENP6 | c.*1592G>C | 3'UTR (SNP) | VAF 28/50 reads (56%) | called by muse, mutect2, varscan2
- SLC46A2 | c.-71G>C | 5'UTR (SNP) | VAF 24/155 reads (15%) | called by muse, mutect2, varscan2
- SLC4A4 | c.254-38C>A | Intron (SNP) | VAF 39/98 reads (40%) | called by muse, mutect2, varscan2
- SLC4A4 | c.254-37C>A | Intron (SNP) | VAF 40/100 reads (40%) | catalogued as CM013898; called by muse, mutect2, varscan2
- SLC5A12 | c.*2007G>C | 3'UTR (SNP) | VAF 14/19 reads (74%) | called by muse, mutect2, varscan2
- SLC5A7 | c.*2806T>A | 3'UTR (SNP) | VAF 89/174 reads (51%) | called by muse, mutect2, varscan2
- ST8SIA2 | c.*241A>G | 3'UTR (SNP) | VAF 22/54 reads (41%) | called by muse, mutect2, varscan2
- TENT5C | c.-83C>A | 5'UTR (SNP) | VAF 45/48 reads (94%) | called by muse, mutect2, varscan2
- TLE4 | c.-783T>G | 5'UTR (SNP) | VAF 22/46 reads (48%) | called by muse, mutect2, varscan2
- TXNDC9 | c.*341T>A | 3'UTR (SNP) | VAF 20/88 reads (23%) | called by muse, mutect2, varscan2
- TXNIP | c.-140T>A | 5'UTR (SNP) | VAF 92/116 reads (79%) | called by muse, mutect2, varscan2
- VPS37B | c.*978G>A | 3'UTR (SNP) | VAF 61/132 reads (46%) | called by muse, mutect2, varscan2
- ZNF345 | c.*1036G>A | 3'UTR (SNP) | VAF 7/111 reads (6%) | called by muse, mutect2
- ZNF507 | c.*2457C>A | 3'UTR (SNP) | VAF 4/29 reads (14%) | called by muse, mutect2
- ZNF507 | c.*4207_*4210del | 3'UTR (DEL) | VAF 58/136 reads (43%) | called by mutect2, pindel, varscan2
